Somatic mutation profile of tumor specimen ALCH-B3GL-TTP1-A (aliquot ALCH-B3GL-TTP1-A-4-0-D-A80D-36) from ALCHEMIST case ALCH-B3GL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Invasive mucinous adenocarcinoma; Age at diagnosis: 65.7 years (24,004 days).
Specimen ALCH-B3GL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5aa31b5-d48f-414a-a6a4-146d1d988855.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GL-NB1-A (Blood Derived Normal), aliquot ALCH-B3GL-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5008b95-6888-4571-8149-631076cdced3

The open-access MAF lists 49 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Intron 3, 5'UTR 2, RNA 2, 3'UTR 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 58/256 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BOD1L2 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.196); catalogued as rs1188882126; called by muse, mutect2, varscan2
- CACNA1G | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs748354117, COSV61721260; called by muse, mutect2, varscan2
- CFHR4 | c.706G>A p.E236K (on ENST00000367416 / NM_001201551.2; = p.E237K on NM_001201550.3) | Missense Mutation (SNP) | VAF 120/979 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as rs1433764723, COSV52231929; called by muse, mutect2, varscan2
- DNAJC14 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs868557401; called by muse, mutect2
- JOSD1 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 134/675 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.856); catalogued as COSV53281818; called by muse, mutect2, varscan2
- OR52N5 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs144845456, COSV57699390; called by muse, mutect2, varscan2
- OR56A1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV57363601; called by muse, varscan2
- PJA1 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 52/502 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs147196192, COSV64054024; called by muse, mutect2, varscan2
- PLEKHH3 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV53190442; called by muse, mutect2, varscan2
- RNF32 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 108/788 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as rs768738781, COSV100311665; called by muse, mutect2, varscan2
- SLC35F2 | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56184143; called by muse, mutect2, varscan2
- STARD13 | c.1192C>T p.P398S (on ENST00000336934 / NM_001243476.3; = p.P280S on NM_052851.3) | Missense Mutation (SNP) | VAF 149/582 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370810988; called by muse, mutect2, varscan2
- AMN | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG3 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 86/498 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BBS2 | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- FAM91A1 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR132 | c.617T>A p.V206D | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- KIFC1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LGR5 | c.213-1G>C p.X71_splice | Splice Site (SNP) | VAF 21/456 reads (5%) | called by muse, mutect2
- MYH7B | c.3041A>T p.K1014M | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NDUFAB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- PIH1D2 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 132/787 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKN3 | c.2321T>C p.M774T | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- RB1 | c.738dup p.N247* | Frame Shift Ins (INS) | VAF 92/511 reads (18%) | called by mutect2, pindel, varscan2
- RC3H1 | c.1727T>G p.M576R | Missense Mutation (SNP) | VAF 140/1068 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- TMEM245 | c.61_66del p.P21_R22del | In Frame Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- TRMT44 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.035); called by muse, mutect2
- XKR3 | c.336G>A p.R112= | Splice Region (SNP) | VAF 48/190 reads (25%) | called by muse, varscan2
- ACSBG1 | c.630C>T p.V210= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs142312677, COSV51907410; called by muse, mutect2, varscan2
- ASCC1 | c.237C>T p.N79= | Silent (SNP) | VAF 54/384 reads (14%) | catalogued as rs770137554; called by muse, mutect2, varscan2
- CCDC87 | c.2175G>C p.L725= | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- CERCAM | c.1599C>A p.L533= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs1169341368, COSV65711691; called by muse, mutect2
- DPY19L4 | c.753G>A p.L251= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- FBXO21 | c.36G>A p.V12= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- FSD1L | c.864G>A p.E288= | Silent (SNP) | VAF 147/419 reads (35%) | catalogued as rs1305212531, COSV65997556; called by muse, mutect2, varscan2
- IFNB1 | c.105T>C p.N35= | Silent (SNP) | VAF 62/604 reads (10%) | called by muse, mutect2, varscan2
- POU4F2 | c.1107G>A p.R369= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- TDRD15 | c.3966C>T p.I1322= | Silent (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- TECTA | c.2037G>A p.E679= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.77463G>A p.T25821= (on ENST00000591111; = p.T18397= on NM_003319.4) | Silent (SNP) | VAF 94/220 reads (43%) | catalogued as rs773950138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGGF1 | c.-263G>T | 5'UTR (SNP) | VAF 114/495 reads (23%) | called by muse, mutect2, varscan2
- CIAO3 | c.574+28A>T | Intron (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- DAPK1 | c.*521A>G | 3'UTR (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- DNM1P47 | n.2700C>T | RNA (SNP) | VAF 39/642 reads (6%) | catalogued as rs752064701; called by muse, mutect2
- GAK | c.268-385C>T | Intron (SNP) | VAF 9/140 reads (6%) | catalogued as rs1361000889; called by muse, mutect2
- SPINK5 | c.475-296G>A | Intron (SNP) | VAF 27/510 reads (5%) | called by muse, mutect2
- TRAV20 | c.-16A>C | 5'UTR (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- XIST | n.9672G>A | RNA (SNP) | VAF 77/520 reads (15%) | called by muse, mutect2, varscan2
